Somatic mutation profile of tumor specimen TCGA-A2-A0EN-01A (aliquot TCGA-A2-A0EN-01A-13D-A099-09) from TCGA case TCGA-A2-A0EN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.6 years (25,771 days).
Specimen TCGA-A2-A0EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b3d54dd-0eda-45c4-9a0c-69aea076cd60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EN-10A (Blood Derived Normal), aliquot TCGA-A2-A0EN-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e4cc7c8-57fe-4446-8eec-3613240e6928

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Frame Shift Del 3, Splice Region 1, Frame Shift Ins 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746536178, COSV62789589; called by muse, mutect2, varscan2
- ANP32E | c.492G>A p.E164= | Splice Region (SNP) | VAF 30/258 reads (12%) | catalogued as rs151007873; called by muse, mutect2, varscan2
- AP5Z1 | c.1456T>A p.S486T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.302); catalogued as COSV100803983; called by muse, mutect2
- CEP104 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769805340, COSV65516722; called by muse, mutect2, varscan2
- FAM47B | c.1013C>G p.T338S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.61); catalogued as COSV61457288; called by muse, mutect2, varscan2
- IL2RG | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as CM930431, COSV52150548; called by muse, mutect2, varscan2
- LCT | c.4580G>A p.G1527E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51559096; called by muse, mutect2, varscan2
- LRRC7 | c.3505G>T p.V1169F (on ENST00000651989 / NM_001370785.2; = p.V1136F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as COSV50556860; called by muse, mutect2, varscan2
- MSX2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756013230, COSV53328477; called by muse, mutect2, varscan2
- MUC4 | c.14413G>T p.D4805Y (on ENST00000463781 / NM_018406.7; = p.D569Y on NM_004532.6) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57807175; called by muse, mutect2
- MYO7A | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs201729482, COSV68683797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC4 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV61595262; called by muse, mutect2, varscan2
- OPRK1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.03); catalogued as rs369742092, COSV55569979; called by muse, mutect2, varscan2
- PHEX | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65079755; called by muse, mutect2, varscan2
- RAB24 | c.605A>G p.H202R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs146377924; called by muse, mutect2, varscan2
- RASA2 | c.1359+1G>T p.X453_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53947621; called by muse, mutect2, varscan2
- RBM39 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV53618594; called by muse, mutect2, varscan2
- RUNX1 | c.286del p.D96Mfs*10 (on ENST00000344691 / NM_001001890.3; = p.D123Mfs*10 on NM_001754.5) | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | catalogued as CM086911; called by mutect2, pindel, varscan2
- SHROOM2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV101098086; called by muse, mutect2
- SLC29A4 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs760181725, COSV51877487; called by muse, mutect2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- TBX4 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV53610400; called by muse, mutect2, varscan2
- TTN | c.55163C>A p.T18388N (on ENST00000591111; = p.T10964N on NM_003319.4) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | PolyPhen probably damaging (0.975); catalogued as COSV60417126; called by muse, mutect2, varscan2
- ZBTB25 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV67199051; called by muse, mutect2, varscan2
- ZP4 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV63913850; called by muse, mutect2, varscan2
- KMT2C | c.11205del p.K3735Nfs*10 | Frame Shift Del (DEL) | VAF 33/207 reads (16%) | called by mutect2, pindel, varscan2
- PSMD1 | c.850dup p.T284Nfs*12 | Frame Shift Ins (INS) | VAF 33/187 reads (18%) | called by mutect2, pindel, varscan2
- SPEN | c.1827_1828del p.F609Lfs*2 | Frame Shift Del (DEL) | VAF 48/238 reads (20%) | called by mutect2, pindel, varscan2
- ARMC7 | c.120C>T p.L40= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV55462348; called by muse, mutect2, varscan2
- MTUS2 | c.2997G>A p.L999= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV70924698; called by muse, mutect2, varscan2
- MYH8 | c.768T>C p.G256= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV67974376; called by muse, mutect2, varscan2
- OLFM4 | c.96C>T p.P32= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs140749392; called by muse, mutect2, varscan2
- TMEM132B | c.939T>A p.T313= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54774420; called by muse, mutect2, varscan2
- TRAV5 | c.159A>G p.L53= | Silent (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
